Somatic mutation profile of tumor specimen ALCH-AEBR-TTR1-A (aliquot ALCH-AEBR-TTR1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-AEBR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.0 years (23,734 days).
Specimen ALCH-AEBR-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbb18610-efb8-4ff1-932e-cb5545549353.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEBR-NB1-A (Blood Derived Normal), aliquot ALCH-AEBR-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8dbfcc7-fefd-413f-a2b1-8399f57c31a2

The open-access MAF lists 241 somatic variants for this specimen: 170 protein-altering or splice-affecting, 43 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 43, Intron 16, Nonsense Mutation 9, Frame Shift Del 8, RNA 4, 3'UTR 4, In Frame Del 4, Frame Shift Ins 3, 5'Flank 3, Splice Region 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASH1L | c.5506C>T p.Q1836* | Nonsense Mutation (SNP) | VAF 225/613 reads (37%) | catalogued as rs1558105796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 120/361 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 121/359 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 120/234 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGO1 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100940830; called by muse, varscan2
- ATP1A2 | c.2935C>T p.P979S | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100767821; called by muse, mutect2
- C1orf112 | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs997421354; called by muse, mutect2, varscan2
- CACNA1D | c.4891T>C p.Y1631H (on ENST00000350061 / NM_001128840.3; = p.Y1651H on NM_000720.4) | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1265988787, COSV99052038; called by muse, mutect2, varscan2
- CDC14C | c.1435A>G p.I479V (on ENST00000428251; = p.I372V on NM_152627.3) | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs765435708; called by muse, varscan2
- CENPF | c.3919T>C p.C1307R | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs769335654; called by muse, mutect2, varscan2
- CEP83 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs559030867; called by muse, mutect2, varscan2
- CPNE8 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 40/204 reads (20%) | catalogued as COSV58851655; called by muse, mutect2, varscan2
- CYYR1 | c.82del p.A29Lfs*42 | Frame Shift Del (DEL) | VAF 72/187 reads (39%) | catalogued as COSV54832938; called by mutect2, pindel, varscan2
- D2HGDH | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 35/127 reads (28%) | catalogued as COSV58321932; called by muse, mutect2, varscan2
- DBX2 | c.555G>T p.R185S | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60337101; called by muse, mutect2, varscan2
- DSG3 | c.2124del p.R709Efs*13 | Frame Shift Del (DEL) | VAF 31/137 reads (23%) | catalogued as COSV57130031; called by mutect2, pindel, varscan2
- EGFLAM | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 148/230 reads (64%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.217); catalogued as rs149843559; called by muse, mutect2, varscan2
- EPHB3 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as rs776201525, COSV57804869; called by muse, mutect2, varscan2
- FAM135B | c.1793del p.G598Vfs*18 | Frame Shift Del (DEL) | VAF 71/168 reads (42%) | catalogued as COSV99417748; called by mutect2, pindel, varscan2
- HDAC7 | c.2645G>A p.R882H (on ENST00000427332; = p.R921H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs771719953; called by muse, mutect2, varscan2
- HTR1F | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.331); catalogued as rs377109125; called by muse, mutect2, varscan2
- IGFN1 | c.3293G>A p.R1098H (on ENST00000295591 / NM_001367841.1; = p.R3555H on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs755448825; called by mutect2, varscan2
- KIAA2026 | c.3621G>T p.E1207D | Missense Mutation (SNP) | VAF 157/206 reads (76%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV67355652; called by muse, mutect2, varscan2
- LRIG2 | c.2916del p.T973Pfs*6 | Frame Shift Del (DEL) | VAF 77/233 reads (33%) | catalogued as COSV100743699; called by mutect2, pindel, varscan2
- LRRC7 | c.1441A>C p.S481R (on ENST00000651989 / NM_001370785.2; = p.S448R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99229146; called by muse, mutect2, varscan2
- MCF2L2 | c.1864C>A p.R622S | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs752647498, COSV61051418; called by muse, mutect2, varscan2
- MRGPRX1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs757667446; called by muse, mutect2
- MROH5 | c.266C>A p.T89N | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1023929848; called by muse, mutect2, varscan2
- MS4A8 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.086); catalogued as COSV55755769; called by muse, mutect2, varscan2
- MUC17 | c.2867C>T p.T956I | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.584); catalogued as rs1343775010, COSV60279668; called by muse, varscan2
- MUTYH | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 71/400 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs200229669, COSV58343650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAPSA | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 79/241 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV53798495; called by muse, mutect2, varscan2
- NBEA | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100077860, COSV59791881; called by muse, mutect2, varscan2
- NCAM2 | c.2455A>G p.I819V | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.952); catalogued as rs377126033, COSV53064750; called by muse, mutect2, varscan2
- NOP53 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 124/369 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.145); catalogued as rs1223467869; called by muse, mutect2, varscan2
- OR4A47 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs12805127, COSV71445129; called by muse, mutect2, varscan2
- OR56A4 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV100417544, COSV100417573; called by muse, mutect2, varscan2
- OR8K3 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV57131294, COSV57132205; called by muse, mutect2, varscan2
- PCDHA7 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 98/453 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV65345501; called by muse, mutect2, varscan2
- PKHD1L1 | c.8738C>T p.S2913L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs1165204640, COSV65746947; called by muse, mutect2, varscan2
- PP2D1 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 21/116 reads (18%) | catalogued as rs781377193, COSV56085270; called by muse, mutect2, varscan2
- RGS12 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122845; called by muse, mutect2, varscan2
- RIMS1 | c.1060A>G p.R354G | Missense Mutation (SNP) | VAF 160/497 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1486994536; called by muse, mutect2, varscan2
- RIMS1 | c.2809A>G p.T937A | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99324158; called by muse, mutect2, varscan2
- SATB2 | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 103/653 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53477260; called by muse, mutect2, varscan2
- SOAT2 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs4244355; called by muse, mutect2, varscan2
- TBC1D12 | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs754532543; called by muse, mutect2, varscan2
- TDRD15 | c.2518A>T p.R840W | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101337978; called by muse, mutect2, varscan2
- TECTA | c.5225G>A p.R1742H | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs549133840; called by muse, mutect2, varscan2
- TENM2 | c.1799C>G p.A600G (on ENST00000518659 / NM_001122679.2; = p.A368G on NM_001080428.3) | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV101318622; called by muse, mutect2, varscan2
- THEMIS | c.446T>C p.M149T | Missense Mutation (SNP) | VAF 117/229 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs759891900, COSV64072282; called by muse, mutect2, varscan2
- TMEM106B | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67544109; called by muse, mutect2, varscan2
- TMEM218 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs575689990, COSV54444770; called by muse, mutect2, varscan2
- USH2A | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 25/242 reads (10%) | catalogued as COSV100240870; called by muse, mutect2, varscan2
- XDH | c.2168G>T p.G723V | Missense Mutation (SNP) | VAF 377/723 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV65148858, COSV65149548; called by muse, mutect2, varscan2
- YES1 | c.285A>G p.I95M | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1568196571; called by muse, mutect2, varscan2
- ZMYND8 | c.79C>T p.H27Y (on ENST00000311275 / NM_001363741.2; = p.H47Y on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as rs1394721933; called by muse, mutect2
- ZNF354B | c.1724A>C p.E575A | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); catalogued as COSV100482962; called by muse, mutect2, varscan2
- ZNF90 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as rs1555705963; called by muse, mutect2, varscan2
- ACTR2 | c.393C>A p.Y131* | Nonsense Mutation (SNP) | VAF 113/239 reads (47%) | called by muse, mutect2, varscan2
- AMBN | c.1048C>G p.H350D | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- ANGPTL3 | c.450A>C p.Q150H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARL5B | c.94A>T p.I32F | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ASPH | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- ATP1B1 | c.836A>T p.Y279F | Missense Mutation (SNP) | VAF 346/820 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- ATP6V0D2 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CALHM1 | c.850del p.E284Rfs*16 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | called by mutect2, pindel, varscan2
- CAND2 | c.1087A>T p.I363F (on ENST00000456430 / NM_001162499.2; = p.I270F on NM_012298.3) | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- CARS1 | c.868_886del p.A290Pfs*9 | Frame Shift Del (DEL) | VAF 15/104 reads (14%) | called by mutect2, pindel, varscan2
- CDC14A | c.686A>G p.K229R | Missense Mutation (SNP) | VAF 210/591 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CFAP65 | c.2873T>A p.V958E | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- CFAP77 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 231/349 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHPF | c.2288C>A p.A763D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CMTR2 | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 81/133 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL13A1 | c.1766_1767insA p.E590Gfs*95 (on ENST00000398978 / NM_001130103.2; = p.E518Gfs*95 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- COL16A1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL18A1 | c.857C>A p.P286Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CRACD | c.2450C>T p.T817M | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CXCL5 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DAW1 | c.236A>T p.N79I | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DDB1 | c.1862-1G>T p.X621_splice | Splice Site (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2
- DECR1 | c.973A>T p.I325L | Missense Mutation (SNP) | VAF 108/211 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DGKI | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- DIAPH3 | c.1610T>C p.I537T (on ENST00000400324 / NM_001042517.2; = p.I274T on NM_030932.3) | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DLG3 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRAM1 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DYRK1B | c.1733C>A p.P578H | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.087); called by muse, mutect2
- EDIL3 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- EFCAB13 | c.2519C>T p.T840I | Missense Mutation (SNP) | VAF 78/89 reads (88%) | SIFT tolerated (0.43); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- EGLN2 | c.826A>T p.I276F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ENTHD1 | c.1773C>A p.S591R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2
- EPHA6 | c.2289C>A p.H763Q (on ENST00000389672 / NM_001080448.3; = p.H155Q on NM_173655.4) | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- EPM2AIP1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- EXD2 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM171A1 | c.2084A>G p.E695G | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM83H | c.2480G>T p.G827V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- FOLH1B | n.901+1G>T | Splice Site (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- FRMD5 | c.830_832del p.P277_E278delinsQ | In Frame Del (DEL) | VAF 18/119 reads (15%) | called by pindel, varscan2
- FRMD5 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); called by muse, varscan2
- FSD2 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FSTL5 | c.1499G>T p.R500M | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- GADD45B | c.242_244del p.F81del | In Frame Del (DEL) | VAF 72/208 reads (35%) | called by mutect2, pindel, varscan2
- GPR137 | c.262A>G p.N88D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRM8 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- HERC2 | c.5219dup p.Q1741Tfs*15 | Frame Shift Ins (INS) | VAF 83/413 reads (20%) | called by mutect2, pindel, varscan2
- HP | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 156/284 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IBSP | c.342T>A p.Y114* | Nonsense Mutation (SNP) | VAF 68/293 reads (23%) | called by muse, mutect2, varscan2
- IGF2 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KLHL7 | c.691G>T p.A231S (on ENST00000339077 / NM_001031710.3; = p.A183S on NM_018846.5) | Missense Mutation (SNP) | VAF 123/424 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LEXM | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LRP2 | c.11318C>T p.P3773L | Missense Mutation (SNP) | VAF 81/470 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRTM4 | c.1273A>G p.I425V | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- MACC1 | c.2293_2301del p.M765_A767del | In Frame Del (DEL) | VAF 84/345 reads (24%) | called by mutect2, pindel, varscan2
- MCM4 | c.1144G>T p.V382F | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MEGF8 | c.3868G>T p.G1290C (on ENST00000251268 / NM_001271938.2; = p.G1223C on NM_001410.3) | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MICALL1 | c.318C>G p.H106Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2
- MTDH | c.284_294del p.V95Gfs*36 | Frame Shift Del (DEL) | VAF 90/160 reads (56%) | called by mutect2, pindel, varscan2
- MUC17 | c.2900C>A p.T967N | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, varscan2
- NCAPG | c.663A>T p.K221N | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NCOA3 | c.3350C>A p.A1117E | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- NSFL1C | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 54/288 reads (19%) | called by muse, mutect2, varscan2
- NXPE4 | c.1519A>T p.S507C (on ENST00000375478 / NM_001077639.2; = p.S223C on NM_017678.3) | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR2A25 | c.181T>A p.F61I | Missense Mutation (SNP) | VAF 75/552 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- OR2T11 | c.524dup p.C176Lfs*2 | Frame Shift Ins (INS) | VAF 54/525 reads (10%) | called by mutect2, pindel, varscan2
- OR5B2 | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- OR8K3 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PIK3AP1 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 39/167 reads (23%) | called by muse, mutect2, varscan2
- PIK3R6 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PLA2G5 | c.211T>G p.Y71D | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHA7 | c.2934G>A p.R978= | Splice Region (SNP) | VAF 46/187 reads (25%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); called by muse, mutect2
- POLE | c.6070C>G p.P2024A | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- POM121L2 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 108/341 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PRKD2 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PRKDC | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAD21L1 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RYR1 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCAF1 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN4A | c.5485C>A p.P1829T | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCRT2 | c.527C>A p.T176K | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDK2 | c.3010A>T p.I1004F | Missense Mutation (SNP) | VAF 149/231 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SETBP1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SI | c.4480G>A p.G1494R | Missense Mutation (SNP) | VAF 77/485 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SIGMAR1 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 355/473 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SKOR2 | c.2908C>A p.P970T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- SLC9C2 | c.2414A>T p.K805I | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SMAD4 | c.905G>T p.W302L | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SPOCK1 | c.1048G>C p.G350R | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SPTBN5 | c.3609G>C p.W1203C | Missense Mutation (SNP) | VAF 94/327 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SRRM2 | c.1526G>T p.R509L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- STARD10 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SUSD1 | c.772_780del p.L258_G260del | In Frame Del (DEL) | VAF 24/191 reads (13%) | called by mutect2, pindel
- TAAR6 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 89/154 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TENM1 | c.6463G>T p.A2155S | Missense Mutation (SNP) | VAF 63/81 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- THOC1 | c.448T>A p.S150T | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- THOC3 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TIGD1 | c.967A>T p.M323L | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS15 | c.60G>C p.M20I | Missense Mutation (SNP) | VAF 137/324 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TMX3 | c.735A>G p.T245= | Splice Region (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
- TRRAP | c.2945A>C p.H982P | Missense Mutation (SNP) | VAF 91/198 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- UNC80 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, varscan2
- URB1 | c.6345G>T p.R2115S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.025); called by muse, mutect2
- VPREB3 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- WDR19 | c.3463C>T p.H1155Y | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XIRP2 | c.517G>T p.V173F (on ENST00000628543; = p.V348F on NM_152381.6) | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ZHX3 | c.947del p.N316Tfs*4 | Frame Shift Del (DEL) | VAF 46/130 reads (35%) | called by mutect2, pindel, varscan2
- ZNF536 | c.3824G>T p.G1275V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ZNF578 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSCAN5A | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZSWIM8 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABL2 | c.2760C>T p.A920= (on ENST00000502732 / NM_007314.4; = p.A905= on NM_005158.5) | Silent (SNP) | VAF 53/505 reads (10%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.2835C>A p.T945= | Silent (SNP) | VAF 69/230 reads (30%) | called by muse, mutect2, varscan2
- ADGRG2 | c.1170G>A p.L390= (on ENST00000379869 / NM_001079858.3; = p.L387= on NM_005756.4) | Silent (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- AGO1 | c.639C>G p.L213= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, varscan2
- AKR1B1 | c.114C>T p.V38= | Silent (SNP) | VAF 281/617 reads (46%) | catalogued as rs779124069, COSV53648937; called by muse, mutect2, varscan2
- ALDOA | c.507C>T p.P169= (on ENST00000642816 / NM_001243177.4; = p.P115= on NM_184041.5) | Silent (SNP) | VAF 97/819 reads (12%) | catalogued as COSV100582048; called by muse, mutect2, varscan2
- ATP4A | c.2793C>A p.T931= | Silent (SNP) | VAF 107/289 reads (37%) | called by muse, mutect2, varscan2
- CD163L1 | c.1032C>T p.S344= | Silent (SNP) | VAF 53/438 reads (12%) | catalogued as rs1464957571, COSV58019640; called by muse, mutect2, varscan2
- CFAP54 | c.171C>G p.P57= | Silent (SNP) | VAF 142/315 reads (45%) | called by muse, mutect2, varscan2
- CIAO1 | c.226C>T p.L76= | Silent (SNP) | VAF 41/293 reads (14%) | catalogued as rs778250049, COSV51499207; called by muse, mutect2, varscan2
- CLEC16A | c.1464G>T p.A488= | Silent (SNP) | VAF 72/228 reads (32%) | catalogued as rs1239707469; called by muse, mutect2, varscan2
- CLSTN2 | c.1635G>A p.L545= | Silent (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- DIDO1 | c.5061G>A p.G1687= | Silent (SNP) | VAF 60/111 reads (54%) | called by muse, mutect2, varscan2
- DLX6 | c.780G>C p.S260= | Silent (SNP) | VAF 160/538 reads (30%) | catalogued as rs377688666, COSV50292851; called by muse, mutect2, varscan2
- EPHA5 | c.534T>A p.A178= | Silent (SNP) | VAF 133/319 reads (42%) | called by muse, mutect2, varscan2
- FBXO40 | c.1362A>T p.G454= | Silent (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- GCM1 | c.294T>C p.P98= | Silent (SNP) | VAF 30/207 reads (14%) | called by muse, mutect2, varscan2
- GRIP2 | c.1239C>A p.L413= (on ENST00000619221; = p.L316= on NM_001080423.4) | Silent (SNP) | VAF 100/298 reads (34%) | called by muse, mutect2, varscan2
- ITK | c.1221T>A p.A407= | Silent (SNP) | VAF 60/330 reads (18%) | called by muse, mutect2, varscan2
- LCTL | c.315C>G p.V105= | Silent (SNP) | VAF 56/206 reads (27%) | catalogued as rs1327588195; called by muse, mutect2, varscan2
- LGALS3BP | c.291G>A p.E97= | Silent (SNP) | VAF 234/288 reads (81%) | called by muse, mutect2, varscan2
- LSS | c.1050G>T p.V350= | Silent (SNP) | VAF 39/220 reads (18%) | called by muse, mutect2, varscan2
- MPV17L2 | c.36G>T p.L12= | Silent (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- MSS51 | c.894G>T p.V298= | Silent (SNP) | VAF 53/188 reads (28%) | called by muse, mutect2, varscan2
- OGFRL1 | c.129G>A p.P43= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs911157157; called by muse, mutect2, varscan2
- ORC1 | c.1485G>T p.L495= | Silent (SNP) | VAF 137/416 reads (33%) | called by muse, mutect2, varscan2
- PCDHA5 | c.309C>A p.I103= | Silent (SNP) | VAF 138/355 reads (39%) | catalogued as rs782613574, COSV100972469; called by muse, mutect2, varscan2
- PDE10A | c.2220C>A p.T740= | Silent (SNP) | VAF 56/208 reads (27%) | catalogued as COSV63100654; called by muse, mutect2, varscan2
- PHACTR3 | c.186G>A p.V62= | Silent (SNP) | VAF 32/198 reads (16%) | called by muse, mutect2, varscan2
- PKD1 | c.9057C>T p.S3019= | Silent (SNP) | VAF 91/544 reads (17%) | catalogued as rs770327858; called by muse, mutect2, varscan2
- RSPH10B2 | c.2002C>T p.L668= | Silent (SNP) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- RSRC1 | c.954G>A p.K318= | Silent (SNP) | VAF 62/201 reads (31%) | catalogued as rs747963263, COSV55834737; called by muse, mutect2, varscan2
- SAMD9 | c.2388C>A p.L796= | Silent (SNP) | VAF 212/437 reads (49%) | catalogued as rs760624546, COSV66072688; called by muse, mutect2, varscan2
- SEC16A | c.141G>T p.P47= | Silent (SNP) | VAF 53/414 reads (13%) | called by muse, mutect2, varscan2
- SLC27A4 | c.1332G>A p.P444= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as rs757141833; called by muse, mutect2, varscan2
- SLC44A3 | c.1470C>T p.L490= (on ENST00000271227 / NM_001114106.3; = p.L442= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- SLITRK4 | c.2259G>A p.R753= | Silent (SNP) | VAF 47/205 reads (23%) | catalogued as COSV62025380; called by muse, mutect2, varscan2
- STXBP5L | c.2937T>C p.F979= | Silent (SNP) | VAF 171/487 reads (35%) | called by muse, mutect2, varscan2
- TCERG1L | c.894T>C p.P298= | Silent (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- TIMD4 | c.988T>C p.L330= | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- ZNF423 | c.2490G>T p.L830= (on ENST00000563137 / NM_001379286.1; = p.L822= on NM_015069.4) | Silent (SNP) | VAF 57/158 reads (36%) | called by muse, mutect2, varscan2
- ZNF550 | c.204G>A p.Q68= | Silent (SNP) | VAF 48/241 reads (20%) | called by muse, mutect2, varscan2
- ZNF579 | c.12G>A p.Q4= | Silent (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- AFAP1 | c.-3+208T>C | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.588G>A | RNA (SNP) | VAF 107/599 reads (18%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.589-35768G>T | Intron (SNP) | VAF 21/57 reads (37%) | catalogued as COSV61624418; called by muse, mutect2, varscan2
- CLCN7 | c.*133G>A | 3'UTR (SNP) | VAF 15/129 reads (12%) | catalogued as rs768968043; called by muse, mutect2, varscan2
- EARS2 | c.*2538C>T | 3'UTR (SNP) | VAF 71/351 reads (20%) | called by muse, mutect2, varscan2
- EMC8 | c.378+12C>A | Intron (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- FAM27E5 | n.284A>T | RNA (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- FCHSD2 | c.705+236G>T | Intron (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- GABRB2 | c.1191+9G>C | Intron (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- GNG2 | c.87+1149G>T | Intron (SNP) | VAF 51/252 reads (20%) | called by muse, mutect2, varscan2
- IRAK4 | c.162-156G>T | Intron (SNP) | VAF 40/254 reads (16%) | called by muse, mutect2, varscan2
- KLF6 | chr10:3785222 T>A | 5'Flank (SNP) | VAF 117/639 reads (18%) | called by muse, varscan2
- LRFN4 | c.*57G>A | 3'UTR (SNP) | VAF 51/212 reads (24%) | catalogued as rs375457407; called by muse, mutect2, varscan2
- LRRC2 | c.-20+540G>A | Intron (SNP) | VAF 83/365 reads (23%) | called by muse, mutect2, varscan2
- MIR513A1 | n.109G>T | RNA (SNP) | VAF 37/243 reads (15%) | called by muse, mutect2, varscan2
- MOGAT3 | chr7:101203169 G>T | 5'Flank (SNP) | VAF 217/482 reads (45%) | called by mutect2, varscan2
- NHS | c.566-52178A>T | Intron (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- NPIPB6 | c.121-3533T>A | Intron (SNP) | VAF 38/452 reads (8%) | called by muse, mutect2
- SLC8A3 | c.2407+57C>T | Intron (SNP) | VAF 45/188 reads (24%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12735G>T | Intron (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- SPCS2P4 | n.348G>C | RNA (SNP) | VAF 68/338 reads (20%) | called by muse, mutect2, varscan2
- SZT2 | c.*1898G>A | 3'UTR (SNP) | VAF 99/254 reads (39%) | called by muse, mutect2, varscan2
- TBC1D10C | c.648+20G>C | Intron (SNP) | VAF 34/200 reads (17%) | called by muse, mutect2, varscan2
- TMEM130 | c.85+511G>T | Intron (SNP) | VAF 56/121 reads (46%) | called by muse, mutect2, varscan2
- USH1C | c.1284+7588C>A | Intron (SNP) | VAF 12/48 reads (25%) | catalogued as CM1211757; called by muse, mutect2
- ZNF208 | c.-38C>A | 5'UTR (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- ZNF516 | chr18:76496495 G>A | 5'Flank (SNP) | VAF 47/189 reads (25%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.370+35C>A | Intron (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
